Somatic mutation profile of tumor specimen TARGET-30-PASNUI-01A (aliquot TARGET-30-PASNUI-01A-01D) from TARGET case TARGET-30-PASNUI, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.1 years (1,126 days).
Specimen TARGET-30-PASNUI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75545eaa-2ab6-4800-bb4d-7b50121bae9a.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASNUI-10A (Blood Derived Normal), aliquot TARGET-30-PASNUI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ede5a847-3569-4775-b28b-916704e77d0d

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.44G>T p.R15I | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs398123324, COSV100910708, COSV64297317, COSV64299553; called by mutect2, varscan2
- RUNX1T1 | c.1672C>A p.Q558K (on ENST00000265814 / NM_001198628.1; = p.Q531K on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV56161605; called by muse, mutect2, varscan2
- FAT2 | c.7333C>A p.H2445N | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (0.91); PolyPhen benign (0.006); called by muse, mutect2
